Surgical pathology report (de-identified scan), TCGA case TCGA-A4-A5Y0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-A5Y0-01A (Primary Tumor).

[page 1 of 4]
Age: Sex: F

Laboratory Patient Report
Print Date/Time:

Surgical Pathology

Histopathological Examination

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site @ Kidney NOS C64.9
9205/10/13

Collected:

Received:

Complete:

Pre-Op Diagnosis : Left Renal Cancer

Order Physician :

Specimens : Kidney, left-

Frozen Diagnosis :

Report

: GROSS EXAMINATION:

The specimen is received fresh in a container labeled with the name of the patient and identified as kidney, left.

Size: 12.2 x 6.1 x 4.4 cm

Weight: 195 grams

Perinephric fat: A moderate amount firmly attached

Ureter dimensions: 9.5 x 0.4 cm

Tumor:

Size: 5 x 5 x 4.9 cm

Description: Friable tan-brown and necrotic, circumscribed

Location: Superior pole

Extent:

Capsule/perinephric fat: bulges capsule, but does not invade fat

Renal sinus: Not involved

Pelvis/calices: Not involved

Renal vein: Not involved

Adrenal: Not applicable

Distance to margins:

Gerota's fascia: 0.2 cm

Ureteral: 12.5 cm

Hilar: 1.5 cm

Renal vein: 1 cm

Other pathology: No

Adrenal: No

Lymph nodes: No

Ink code: Gerota's fascia overlying mass-black, hilar soft tissue margin-blue

Block summary:

1. Ureteral and vascular margins

2. Hilar soft tissue margin, en face

[page 2 of 4]
- [REDACTED]
3. Mass with Gerota's fascia
4. Mass with renal sinus and adjacent vessels
5. Mass with adjacent parenchyma
6. Additional mass
7. Uninvolved parenchyma
- [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

Kidney, left, nephrectomy:

- Papillary renal cell carcinoma (type 2), Fuhrman grade 2,
5 cm, confined to kidney with negative margins (see

CANCER CASE SUMMARY CHECKLIST

KIDNEY: Nephrectomy (Version 3.1.0.1.)

PROCEDURE: Radical nephrectomy

SPECIMEN LATERALITY: Left

TUMOR SIZE:

Greatest dimension: 5 cm

TUMOR FOCALITY: Unifocal

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGIC TYPE: Papillary renal cell carcinoma (type 2)

SARCOMATOID FEATURES: Not identified.

HISTOLOGIC GRADE: Fuhrman nuclear grade:

G2: Nuclei slightly irregular approximately 15 microns
nucleoli evident

MICROSCOPIC TUMOR EXTENSION: Tumor limited to kidney

MARGINS: Uninvolved by invasive carcinoma.

PATHOLOGIC STAGING (pTNM):

Primary Tumor (pT): pT1: Tumor 7 cm or less in greatest
dimension, limited to the kidney

Regional Lymph Nodes (pN): pNX: Regional lymph nodes cannot
be assessed (no nodes submitted or found)

Distant Metastasis (pM): Not applicable.

PATHOLOGIC FINDINGS IN NONNEOPLASTIC KIDNEY:

- Nephrosclerosis.

- Chronic inflammation.

COMMENT:

Intradepartmental consultation obtained.

Results communicated to [REDACTED] on

[page 3 of 4]
[REDACTED] Pathologist

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

[REDACTED] Page 2 of 3

Electronically Signed by:
[REDACTED]

[page 4 of 4]
THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Page 3 of 3

Source: NCI Genomic Data Commons file 95e79974-e274-4dae-8e93-a1c8d2b9fcb6 (TCGA-A4-A5Y0.043FAD7D-AF79-4904-9CCA-5B7C6D848565.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).